TARGET case TARGET-40-PARGNA — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/01adb1db-9dc1-5e6a-b28f-5ed5a2ba4c83

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 11 years; Vital status: Dead; Days to death: 359 days.

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.2; Tissue or organ of origin: Long bones of lower limb and associated joints; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 11.4 years (4,147 days); Year of diagnosis: 2007; Metastasis at diagnosis: Metastasis, NOS; Days to last follow up: 359 days; Sites of involvement: Lung, NOS / Bone, NOS.
   Treatment given: Protocol identifier: P9851.

Follow-up (2 entries)
- Days to follow up: 244 days; Progression or recurrence: Yes; Days to progression: 244 days; Days to first event: 244 days; First event: Relapse.
- Days to follow up: 359 days; Progression or recurrence: Yes; Progression or recurrence type: Local; Year of follow up: 2008.

Biospecimens (1 sample)
- Sample TARGET-40-PARGNA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-PARGNA-01A-01:
- Specimen Type: Frozen solid tumor
- Diagnosis Confirmed: yes
- % Tumor Nuclei: Top from Biopsy: 85
- % Non Tumor Nuclei: Top from Biopsy: 15
- % Cellular Tumor: Top from Biopsy: 30
- % Normal: Top from Biopsy: 40
- % Stroma: Top from Biopsy: 0
- % Necrosis: Top from Biopsy: 30
- % Tumor Nuclei: Bottom from Biopsy: 90
- % Non Tumor Nuclei: Bottom from Biopsy: 10
- % Cellular Tumor: Bottom from Biopsy: 10
- % Normal: Bottom from Biopsy: 85
- % Stroma: Bottom from Biopsy: 0
- % Necrosis: Bottom from Biopsy: 5
- PASS/FAIL: pass

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Validation_20230329.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 359
- Disease at diagnosis: Metastatic (confirmed)
- Metastasis site: Bone and lung
- Primary tumor site: Leg/foot
- Specific tumor site: Femur
- Primary site progression: Yes
- Time to first enrollment on relapse protocol in days: 275
